Somatic mutation profile of tumor specimen ALCH-B29Q-TTP1-A (aliquot ALCH-B29Q-TTP1-A-1-0-D-A775-36) from ALCHEMIST case ALCH-B29Q, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 65.3 years (23,843 days).
Specimen ALCH-B29Q-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b85b1017-6a96-432a-932f-43710019a9c5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B29Q-NB1-A (Blood Derived Normal), aliquot ALCH-B29Q-NB1-A-1-0-D-A775-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/28147d4d-2e16-41e0-b9b6-4bc9fd85bff8

The open-access MAF lists 135 somatic variants for this specimen: 86 protein-altering or splice-affecting, 32 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 82, Silent 32, Intron 5, 3'UTR 4, RNA 4, 5'UTR 2, Nonsense Mutation 2, Splice Site 2, 3'Flank 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AFDN | c.5264G>A p.G1755E (on ENST00000447894 / NM_001366320.1; = p.G1674E on NM_001207008.1) | Missense Mutation (SNP) | VAF 19/616 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.776); catalogued as rs1407485868; called by muse, mutect2
- ASPM | c.3421G>T p.G1141C | Missense Mutation (SNP) | VAF 20/476 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54130446; called by muse, mutect2
- CCK | c.209G>T p.R70L | Missense Mutation (SNP) | VAF 13/222 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV58184345; called by muse, mutect2
- CDK4 | c.289G>C p.D97H | Missense Mutation (SNP) | VAF 24/943 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.212); catalogued as rs1060501932; ClinVar: uncertain significance; called by muse, mutect2
- CLDN6 | c.325G>C p.E109Q | Missense Mutation (SNP) | VAF 30/566 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.065); catalogued as COSV100172112; called by muse, mutect2
- CSMD3 | c.8083C>A p.P2695T | Missense Mutation (SNP) | VAF 18/400 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.811); catalogued as COSV99843289, COSV99845417; called by muse, mutect2
- DDX51 | c.566G>A p.R189K | Missense Mutation (SNP) | VAF 22/690 reads (3%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as rs1565955427; called by muse, mutect2
- EGFLAM | c.2827G>A p.D943N (on ENST00000354891 / NM_001205301.2; = p.D935N on NM_152403.4) | Missense Mutation (SNP) | VAF 14/406 reads (3%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.906); catalogued as COSV59305524; called by muse, mutect2
- EGR4 | c.1571G>A p.R524H (on ENST00000545030; = p.R421H on NM_001965.4) | Missense Mutation (SNP) | VAF 14/420 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV71532073; called by muse, mutect2
- HBA2 | c.358C>A p.P120T | Missense Mutation (SNP) | VAF 20/708 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.584); catalogued as CM1511051; called by muse, mutect2
- KDR | c.2180T>A p.V727E | Missense Mutation (SNP) | VAF 20/692 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55775782; called by muse, mutect2
- KRTAP11-1 | c.262C>A p.Q88K | Missense Mutation (SNP) | VAF 16/541 reads (3%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as COSV60094603; called by muse, mutect2
- LRP1B | c.3982G>T p.V1328L | Missense Mutation (SNP) | VAF 20/344 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.029); catalogued as COSV67284941; called by muse, mutect2
- LRRC30 | c.535C>T p.P179S | Missense Mutation (SNP) | VAF 10/250 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67302085; called by muse, mutect2
- LSM2 | c.203G>A p.R68Q | Missense Mutation (SNP) | VAF 24/782 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs774140291, COSV65151787; called by muse, mutect2
- MRFAP1 | c.268G>C p.E90Q | Missense Mutation (SNP) | VAF 10/297 reads (3%) | SIFT tolerated (0.12); PolyPhen benign (0.319); catalogued as COSV100307700, COSV100307713; called by muse, mutect2
- MYO18B | c.1062G>C p.Q354H | Missense Mutation (SNP) | VAF 10/268 reads (4%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.081); catalogued as COSV100123501; called by muse, mutect2
- NUP98 | c.988C>G p.L330V | Missense Mutation (SNP) | VAF 21/472 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV61431120; called by muse, mutect2
- PLCB3 | c.1156G>A p.E386K | Missense Mutation (SNP) | VAF 18/563 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54191452; called by muse, mutect2
- RBM10 | c.1435+1G>T p.X479_splice | Splice Site (SNP) | VAF 6/88 reads (7%) | catalogued as COSV61312299; called by muse, mutect2
- SEMG1 | c.629C>A p.T210N | Missense Mutation (SNP) | VAF 22/258 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.829); catalogued as COSV54873381; called by muse, mutect2
- SLC7A4 | c.1628C>A p.P543H | Missense Mutation (SNP) | VAF 8/151 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV60385820; called by muse, mutect2
- TRPM2 | c.1426G>T p.E476* | Nonsense Mutation (SNP) | VAF 13/342 reads (4%) | catalogued as COSV55973829; called by muse, mutect2
- TTLL12 | c.430C>T p.R144C | Missense Mutation (SNP) | VAF 17/418 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1386294632, COSV99333588; called by muse, mutect2
- ZFHX4 | c.6466G>C p.E2156Q | Missense Mutation (SNP) | VAF 10/299 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV51498947; called by muse, mutect2
- ZNF85 | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 8/202 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV60213149; called by muse, mutect2
- AC011005.1 | c.351G>C p.E117D | Missense Mutation (SNP) | VAF 11/275 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2
- ADAM15 | c.1789G>A p.D597N | Missense Mutation (SNP) | VAF 18/602 reads (3%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.707); called by muse, mutect2
- ADAMTS17 | c.514C>T p.P172S | Missense Mutation (SNP) | VAF 28/868 reads (3%) | SIFT tolerated (0.83); PolyPhen benign (0.006); called by muse, mutect2
- ADCY10 | c.4303G>A p.E1435K | Missense Mutation (SNP) | VAF 16/500 reads (3%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.918); called by muse, mutect2
- ATP2A2 | c.2434G>A p.D812N | Missense Mutation (SNP) | VAF 30/1136 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2
- BCL2L2 | c.106G>T p.G36C | Missense Mutation (SNP) | VAF 6/91 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); called by muse, mutect2
- BEND4 | c.1235G>C p.R412T | Missense Mutation (SNP) | VAF 14/356 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- BRWD1 | c.3142G>A p.D1048N | Missense Mutation (SNP) | VAF 8/192 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- CAP2 | c.55G>T p.E19* | Nonsense Mutation (SNP) | VAF 24/900 reads (3%) | called by muse, mutect2
- CASK | c.1991C>G p.S664C | Missense Mutation (SNP) | VAF 13/248 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.449); called by muse, mutect2
- CCDC105 | c.121C>A p.Q41K | Missense Mutation (SNP) | VAF 16/408 reads (4%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2
- COL9A3 | c.1736C>A p.P579H | Missense Mutation (SNP) | VAF 18/192 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2
- CRACD | c.565G>C p.E189Q | Missense Mutation (SNP) | VAF 7/152 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.466); called by muse, mutect2
- CRISP1 | c.490C>A p.Q164K | Missense Mutation (SNP) | VAF 17/518 reads (3%) | SIFT tolerated (0.74); PolyPhen benign (0); called by muse, mutect2
- CSMD1 | c.5864C>A p.S1955Y (on ENST00000520002; = p.S1954Y on NM_033225.6) | Missense Mutation (SNP) | VAF 22/449 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); called by muse, mutect2
- ENGASE | c.1738G>T p.D580Y | Missense Mutation (SNP) | VAF 19/454 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2
- F13A1 | c.2102C>T p.S701F | Missense Mutation (SNP) | VAF 24/597 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.19); called by muse, mutect2
- FAM71A | c.65A>G p.N22S | Missense Mutation (SNP) | VAF 5/106 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.719); called by muse, mutect2
- FARSA | c.1351A>T p.N451Y | Missense Mutation (SNP) | VAF 12/360 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); called by muse, mutect2
- FLVCR1 | c.713G>T p.C238F | Missense Mutation (SNP) | VAF 16/427 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- FRMPD1 | c.943G>C p.E315Q | Missense Mutation (SNP) | VAF 12/292 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GPR119 | c.145G>T p.V49L | Missense Mutation (SNP) | VAF 16/476 reads (3%) | SIFT tolerated (0.5); PolyPhen benign (0.026); called by muse, mutect2
- GPR26 | c.358C>T p.L120F | Missense Mutation (SNP) | VAF 14/290 reads (5%) | SIFT tolerated (0.56); PolyPhen benign (0.01); called by muse, mutect2
- HS3ST2 | c.311C>A p.S104Y | Missense Mutation (SNP) | VAF 12/182 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); called by muse, mutect2
- IFI30 | c.716C>T p.S239F | Missense Mutation (SNP) | VAF 20/566 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.083); called by muse, mutect2
- IGF2R | c.1324G>T p.G442W | Missense Mutation (SNP) | VAF 6/128 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KCNA6 | c.994G>T p.G332W | Missense Mutation (SNP) | VAF 18/305 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- KSR1 | c.613A>T p.S205C (on ENST00000644974 / NM_001367810.1; = p.S68C on NM_014238.2) | Missense Mutation (SNP) | VAF 16/280 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.646); called by muse, mutect2
- LRP1B | c.11158C>A p.P3720T | Missense Mutation (SNP) | VAF 14/291 reads (5%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.994); called by muse, mutect2
- MAP3K10 | c.2738C>T p.P913L | Missense Mutation (SNP) | VAF 21/524 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.038); called by muse, mutect2
- MATR3 | c.458G>T p.G153V | Missense Mutation (SNP) | VAF 11/233 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.58); called by muse, mutect2
- NACAD | c.1142G>T p.R381L | Missense Mutation (SNP) | VAF 11/154 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2
- NEB | c.9364G>T p.D3122Y | Missense Mutation (SNP) | VAF 14/288 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NHLRC3 | c.28G>T p.G10C | Missense Mutation (SNP) | VAF 47/856 reads (5%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.764); called by muse, mutect2
- NRDC | c.3190G>C p.E1064Q | Missense Mutation (SNP) | VAF 8/156 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- PAX3 | c.832G>T p.A278S | Missense Mutation (SNP) | VAF 34/576 reads (6%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.867); called by muse, mutect2
- PDSS2 | c.466C>T p.H156Y | Missense Mutation (SNP) | VAF 14/438 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2
- PEBP4 | c.319C>G p.Q107E | Missense Mutation (SNP) | VAF 17/572 reads (3%) | SIFT tolerated (0.33); PolyPhen benign (0.006); called by muse, mutect2
- PGK1 | c.280C>G p.L94V | Missense Mutation (SNP) | VAF 30/920 reads (3%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2
- PPP1R9B | c.620C>T p.T207M | Missense Mutation (SNP) | VAF 12/326 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); called by muse, mutect2
- PRPS1 | c.191A>G p.N64S | Missense Mutation (SNP) | VAF 28/705 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.014); called by muse, mutect2
- RASAL2 | c.1628G>T p.G543V | Missense Mutation (SNP) | VAF 21/417 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.467); called by muse, mutect2
- RBM15B | c.542G>A p.R181H | Missense Mutation (SNP) | VAF 12/186 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.535); called by muse, mutect2
- RGS9 | c.1750A>T p.R584W | Missense Mutation (SNP) | VAF 17/432 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.858); called by muse, mutect2
- RUNX2 | c.1217C>T p.S406L (on ENST00000371438; = p.S384L on NM_001015051.3) | Missense Mutation (SNP) | VAF 57/1554 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.15); called by muse, mutect2
- RYR2 | c.4999C>A p.L1667I | Missense Mutation (SNP) | VAF 14/436 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); called by muse, mutect2
- SIGLEC1 | c.4897C>A p.L1633M | Missense Mutation (SNP) | VAF 10/212 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2
- SPACA7 | c.95-1G>T p.X32_splice | Splice Site (SNP) | VAF 8/92 reads (9%) | called by muse, mutect2
- SPATA31A6 | c.1072A>C p.K358Q | Missense Mutation (SNP) | VAF 50/1232 reads (4%) | SIFT tolerated (0.34); PolyPhen benign (0.108); called by muse, mutect2
- SPECC1 | c.3178G>T p.A1060S | Missense Mutation (SNP) | VAF 19/636 reads (3%) | SIFT tolerated (0.34); PolyPhen benign (0.326); called by muse, mutect2
- STAG2 | c.1331A>T p.E444V | Missense Mutation (SNP) | VAF 10/249 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.007); called by muse, mutect2
- SUN2 | c.1492G>A p.E498K | Missense Mutation (SNP) | VAF 20/555 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.017); called by muse, mutect2
- TBC1D2 | c.192G>T p.W64C | Missense Mutation (SNP) | VAF 13/256 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2
- TCHHL1 | c.2087G>C p.R696T | Missense Mutation (SNP) | VAF 14/476 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.748); called by muse, mutect2
- TENM1 | c.4633T>A p.Y1545N | Missense Mutation (SNP) | VAF 20/544 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TNRC6A | c.1802G>T p.W601L | Missense Mutation (SNP) | VAF 15/187 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- TNRC6A | c.1803G>T p.W601C | Missense Mutation (SNP) | VAF 14/182 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- USP54 | c.1253C>A p.S418Y | Missense Mutation (SNP) | VAF 11/291 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- WDR45 | c.508C>A p.Q170K (on ENST00000376372 / NM_001029896.2; = p.Q171K on NM_007075.3) | Missense Mutation (SNP) | VAF 11/236 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.254); called by muse, mutect2
- ZNF667 | c.1215G>C p.Q405H | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.804); called by muse, mutect2
- AKAP4 | c.1866G>A p.Q622= | Silent (SNP) | VAF 9/238 reads (4%) | catalogued as rs1557203860; called by muse, mutect2
- ALPK1 | c.2832G>T p.G944= | Silent (SNP) | VAF 12/281 reads (4%) | called by muse, mutect2
- CASR | c.1623C>G p.L541= (on ENST00000490131; = p.L618= on NM_000388.4) | Silent (SNP) | VAF 12/277 reads (4%) | called by muse, mutect2
- CDH10 | c.2037A>T p.A679= | Silent (SNP) | VAF 36/1210 reads (3%) | called by muse, mutect2
- CFAP54 | c.7305A>G p.E2435= | Silent (SNP) | VAF 24/668 reads (4%) | called by muse, mutect2
- CRB1 | c.741C>T p.F247= | Silent (SNP) | VAF 17/580 reads (3%) | called by muse, mutect2
- EML6 | c.3387A>T p.T1129= | Silent (SNP) | VAF 8/180 reads (4%) | called by muse, mutect2
- F8 | c.2538T>C p.S846= | Silent (SNP) | VAF 6/132 reads (5%) | catalogued as rs782556434; called by muse, mutect2
- FUT4 | c.1152C>T p.D384= | Silent (SNP) | VAF 36/371 reads (10%) | catalogued as COSV100708145; called by muse, mutect2, varscan2
- GLRA1 | c.1308C>G p.L436= (on ENST00000455880 / NM_001146040.2; = p.L428= on NM_000171.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/453 reads (4%) | called by muse, mutect2
- IGKV2D-24 | c.282A>T p.T94= | Silent (SNP) | VAF 18/426 reads (4%) | called by muse, mutect2
- KRT71 | c.885A>G p.L295= | Silent (SNP) | VAF 12/352 reads (3%) | called by muse, mutect2
- LRP1B | c.3984G>T p.V1328= | Silent (SNP) | VAF 20/353 reads (6%) | catalogued as rs1205183402; called by muse, mutect2
- LRRC46 | c.838C>T p.L280= | Silent (SNP) | VAF 11/352 reads (3%) | called by muse, mutect2
- LTBP1 | c.3567G>T p.P1189= (on ENST00000404816 / NM_206943.4; = p.P863= on NM_000627.4) | Silent (SNP) | VAF 20/416 reads (5%) | catalogued as COSV55377220; called by muse, mutect2
- NRIP1 | c.2259G>A p.V753= | Silent (SNP) | VAF 17/329 reads (5%) | called by muse, mutect2
- NRL | c.132C>T p.Y44= | Silent (SNP) | VAF 21/715 reads (3%) | called by muse, mutect2
- NYX | c.783G>T p.L261= | Silent (SNP) | VAF 11/350 reads (3%) | called by muse, mutect2
- OR4N5 | c.489C>A p.I163= | Silent (SNP) | VAF 22/633 reads (3%) | called by muse, mutect2
- OR9Q2 | c.792A>T p.T264= | Silent (SNP) | VAF 14/409 reads (3%) | called by muse, mutect2
- OTOG | c.7878T>A p.T2626= | Silent (SNP) | VAF 14/292 reads (5%) | called by muse, mutect2
- PTPRJ | c.2625A>G p.K875= | Silent (SNP) | VAF 11/283 reads (4%) | called by muse, mutect2
- RAB27A | c.324C>G p.L108= | Silent (SNP) | VAF 16/428 reads (4%) | called by muse, mutect2
- RBFOX1 | c.129C>A p.A43= | Silent (SNP) | VAF 13/156 reads (8%) | catalogued as rs776138625, COSV60965210; called by muse, mutect2
- REEP4 | c.231C>G p.L77= | Silent (SNP) | VAF 18/474 reads (4%) | catalogued as rs1458975848, COSV57942941; called by muse, mutect2
- SFPQ | c.786C>T p.G262= | Silent (SNP) | VAF 9/209 reads (4%) | called by muse, mutect2
- SMPDL3B | c.1032G>C p.L344= | Silent (SNP) | VAF 5/85 reads (6%) | called by muse, mutect2
- SPATA3 | c.78C>A p.S26= | Silent (SNP) | VAF 46/702 reads (7%) | called by muse, mutect2
- STX3 | c.528C>T p.I176= | Silent (SNP) | VAF 20/488 reads (4%) | called by muse, mutect2
- TFAP4 | c.213C>G p.L71= | Silent (SNP) | VAF 13/254 reads (5%) | called by muse, mutect2
- VWC2 | c.939G>T p.R313= | Silent (SNP) | VAF 19/554 reads (3%) | called by muse, mutect2
- ZNF860 | c.24G>A p.Q8= | Silent (SNP) | VAF 14/344 reads (4%) | catalogued as COSV100824461; called by muse, mutect2
- AL132655.6 | chr20:58840778 C>A | 5'Flank (SNP) | VAF 18/423 reads (4%) | called by muse, mutect2
- CMAHP | n.1939C>G | RNA (SNP) | VAF 10/222 reads (5%) | called by muse, mutect2
- CUBN | c.*20C>T | 3'UTR (SNP) | VAF 24/840 reads (3%) | catalogued as rs1197240725, COSV100912419; called by muse, mutect2
- DRGX | c.-33G>T | 5'UTR (SNP) | VAF 10/260 reads (4%) | called by muse, mutect2
- ESR1 | c.452+838C>G | Intron (SNP) | VAF 13/292 reads (4%) | called by muse, mutect2
- GABRA6 | c.-5G>T | 5'UTR (SNP) | VAF 30/1103 reads (3%) | catalogued as COSV99195200; called by muse, mutect2
- GPC1 | c.167-960G>T | Intron (SNP) | VAF 14/210 reads (7%) | called by muse, mutect2
- HOXC11 | c.*35G>A | 3'UTR (SNP) | VAF 10/216 reads (5%) | called by muse, mutect2
- LDLRAD2 | c.*2022G>A | 3'UTR (SNP) | VAF 20/512 reads (4%) | called by muse, mutect2
- LINC01567 | n.182G>T | RNA (SNP) | VAF 13/396 reads (3%) | called by muse, mutect2
- LINC01567 | n.181T>C | RNA (SNP) | VAF 11/392 reads (3%) | called by muse, mutect2
- RAB40C | chr16:630307 G>T | 3'Flank (SNP) | VAF 15/211 reads (7%) | called by muse, mutect2
- SART3 | c.961-24C>G | Intron (SNP) | VAF 23/675 reads (3%) | called by muse, mutect2
- SNORD115-10 | n.65G>C | RNA (SNP) | VAF 18/634 reads (3%) | called by muse, mutect2
- UPF3A | c.*11G>A | 3'UTR (SNP) | VAF 30/640 reads (5%) | called by muse, mutect2
- ZEB1 | c.58+43927G>T | Intron (SNP) | VAF 21/553 reads (4%) | called by muse, mutect2
- ZNF696 | c.65-297C>T | Intron (SNP) | VAF 18/380 reads (5%) | catalogued as rs1452664693; called by muse, mutect2
